FM case AD15801 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas.
https://portal.gdc.cancer.gov/cases/103c2ba6-ab86-4b2b-8c25-196f38328338

Male, 55.2 years: Neuroendocrine carcinoma, NOS (ICD-O-3 8246/3). Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Tumor.
